Somatic mutation profile of tumor specimen MMRF_1639_2_BM_CD138pos (aliquot MMRF_1639_2_BM_CD138pos_T1_KHS5U_L08648) from MMRF case MMRF_1639, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,581 days).
Specimen MMRF_1639_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c86dd007-0494-4150-b9a1-42c81e2a783f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1639_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1639_1_PB_Whole_C3_KBS5U_L04320; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c808c8db-b266-458c-87d1-391868aac4b3

The open-access MAF lists 104 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 22, Intron 14, Silent 12, Nonsense Mutation 6, 5'UTR 6, Splice Site 3, RNA 2, 3'Flank 2, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- C14orf93 | c.1337G>A p.R446H | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs143379381; called by muse, mutect2, varscan2
- CDH12 | c.941G>C p.G314A | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.999); catalogued as COSV66426630; called by muse, mutect2, varscan2
- CDH7 | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs562336351; called by muse, mutect2, varscan2
- CDH8 | c.1536+6T>G | Splice Region (SNP) | VAF 20/115 reads (17%) | catalogued as COSV54848692; called by muse, mutect2, varscan2
- COL6A5 | c.6898C>T p.Q2300* (on ENST00000312481; = p.Q2296* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99592223; called by muse, mutect2, varscan2
- FAM187B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1389739363; called by muse, mutect2
- FOXRED1 | c.1241A>C p.N414T | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200742305; called by muse, mutect2, varscan2
- GK | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV66735438; called by muse, mutect2
- HEPACAM2 | c.364G>A p.V122M (on ENST00000394468 / NM_001039372.4; = p.V110M on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139218067; called by muse, mutect2, varscan2
- IGHV1-69D | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1283966798; called by muse, varscan2
- IGHV2-70 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs573185871; called by muse, varscan2
- IGHV2-70D | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1169792576; called by muse, varscan2
- LAMB1 | c.1069G>A p.V357I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs200303288; called by muse, mutect2, varscan2
- MAP3K1 | c.3590C>T p.A1197V | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); catalogued as rs763984353; called by muse, mutect2, varscan2
- OSCP1 | c.955C>T p.R319W (on ENST00000356637 / NM_001330493.1; = p.R309W on NM_145047.5) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406005863; called by muse, varscan2
- RAD9B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs1439336615, COSV63778564; called by muse, mutect2, varscan2
- RB1 | c.1696-1G>T p.X566_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as CS951523, COSV57329272; called by muse, mutect2, varscan2
- RFX2 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1015514275; called by muse, mutect2, varscan2
- RHOU | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs745690593; called by muse, mutect2, varscan2
- SCN9A | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1060502050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC16A9 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as rs747080169; called by muse, mutect2, varscan2
- SPRED1 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.758); catalogued as COSV54434997; called by muse, mutect2, varscan2
- BDP1 | c.6995+1G>A p.X2332_splice | Splice Site (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- BRDT | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2
- BRWD3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- C17orf80 | c.1505T>G p.L502R | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CLCN1 | c.1850C>A p.S617* | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- HERPUD1 | c.617_618del p.V206Gfs*16 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by pindel, varscan2
- IGHV2-70D | c.206T>A p.L69H | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- IRAK1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITK | c.713A>C p.E238A | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- LRRC4 | c.1289C>T p.A430V | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- LYZL1 | c.515G>A p.W172* (on ENST00000375500; = p.W126* on NM_032517.6) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | called by muse, varscan2
- MAGI3 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NONO | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPAT | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); called by muse, mutect2
- NSD3 | c.3241G>A p.V1081I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PDSS1 | c.1108-1G>C p.X370_splice | Splice Site (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- PDXDC1 | c.925C>A p.P309T | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- PLEKHG7 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- SMS | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- USH2A | c.859G>T p.E287* | Nonsense Mutation (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2, varscan2
- ZNF727 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF76 | c.1642A>C p.N548H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.054); called by mutect2, varscan2
- BNIP2 | c.264G>A p.P88= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs774065595; called by muse, mutect2, varscan2
- DUSP2 | c.414C>T p.C138= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV56619333; called by muse, mutect2, varscan2
- FREM1 | c.5736G>T p.R1912= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- GK | c.522T>A p.L174= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- IGHV2-70D | c.156A>T p.G52= | Silent (SNP) | VAF 18/104 reads (17%) | called by muse, varscan2
- KIF1B | c.3387C>A p.I1129= (on ENST00000377086 / NM_001365952.1; = p.I1083= on NM_015074.3) | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99823906; called by muse, mutect2
- LINGO3 | c.1614C>T p.F538= | Silent (SNP) | VAF 36/144 reads (25%) | called by muse, mutect2, varscan2
- MYRF | c.1302C>T p.H434= (on ENST00000278836 / NM_001127392.3; = p.H425= on NM_013279.4) | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs370594037; called by muse, mutect2
- PCDHAC1 | c.1362T>A p.V454= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- PNMA8A | c.711T>G p.A237= | Silent (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- SHC4 | c.1563G>A p.L521= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- ZFAT | c.2589G>A p.E863= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- ABI3BP | c.-14G>A | 5'UTR (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2
- ANKFY1 | c.2240+62T>A | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs905756985; called by muse, mutect2
- ARNTL2 | chr12:27422929 T>C | 3'Flank (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- ASPG | c.192-73C>T | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as rs753062458; called by muse, mutect2, varscan2
- ATP1B4 | c.*2161T>C | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.1038+119C>G | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1401701760; called by muse, mutect2
- CBLN4 | c.-1149G>A | 5'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- CCNJL | n.42A>G | RNA (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2, varscan2
- CD82 | c.262-42C>T | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as rs761902871; called by muse, mutect2, varscan2
- CHRM2 | c.-47+33691A>G | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- CLSTN1 | c.*925C>T | 3'UTR (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- CNOT3 | c.-50-1439G>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- COL13A1 | c.-240C>T | 5'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.*92C>T | 3'UTR (SNP) | VAF 35/171 reads (20%) | catalogued as rs1281991658; called by muse, mutect2, varscan2
- CTNND1 | c.*2769G>C | 3'UTR (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- DTL | c.*1559del | 3'UTR (DEL) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- ERLIN2 | chr8:37736249 ins A | 5'Flank (INS) | VAF 10/40 reads (25%) | catalogued as rs1003583312; called by mutect2, varscan2
- FAM169A | c.*1725A>G | 3'UTR (SNP) | VAF 13/72 reads (18%) | catalogued as rs1010562892; called by muse, mutect2, varscan2
- FAM71E1 | c.259+65G>A | Intron (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100618588; called by muse, mutect2
- FANCD2 | c.696-67C>T | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55049264; called by muse, mutect2, varscan2
- FMO5 | c.-38+9C>A | Intron (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- GSR | c.*1G>A | 3'UTR (SNP) | VAF 21/128 reads (16%) | catalogued as rs915133836; called by muse, mutect2, varscan2
- IFT27 | c.463-13A>G | Intron (SNP) | VAF 5/30 reads (17%) | catalogued as rs777805137; called by muse, mutect2, varscan2
- IGF2BP3 | c.*24A>G | 3'UTR (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*4222_*4223insA | 3'UTR (INS) | VAF 6/54 reads (11%) | catalogued as COSV99289058; called by pindel, varscan2
- IGFN1 | c.*30C>A | 3'UTR (SNP) | VAF 52/358 reads (15%) | catalogued as COSV99812846; called by muse, mutect2, varscan2
- IGHV6-1 | c.-37T>A | 5'UTR (SNP) | VAF 7/13 reads (54%) | catalogued as rs373665496; called by muse, varscan2
- LRCH2 | c.*1296T>A | 3'UTR (SNP) | VAF 21/58 reads (36%) | catalogued as rs1246057069; called by muse, mutect2, varscan2
- MIER3 | c.*1336G>C | 3'UTR (SNP) | VAF 10/82 reads (12%) | called by muse, mutect2, varscan2
- NR2F2 | c.-470G>A | 5'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- NR5A2 | c.1110+9232G>A | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- OR52L2P | n.561C>A | RNA (SNP) | VAF 13/71 reads (18%) | called by muse, varscan2
- PIK3CB | c.*1C>T | 3'UTR (SNP) | VAF 73/330 reads (22%) | catalogued as rs756330302; called by muse, mutect2, varscan2
- PSCA | c.*235C>T | 3'UTR (SNP) | VAF 34/267 reads (13%) | catalogued as rs1291589002; called by muse, mutect2
- RAC2 | c.-58del | 5'UTR (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- RNF19A | c.*488T>G | 3'UTR (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- RSBN1 | c.*4110_*4114del | 3'UTR (DEL) | VAF 5/20 reads (25%) | catalogued as rs772042986; called by mutect2, varscan2
- SCML4 | c.488-65C>T | Intron (SNP) | VAF 10/18 reads (56%) | catalogued as rs531225110; called by muse, mutect2, varscan2
- SPRED2 | c.27-21745A>G | Intron (SNP) | VAF 34/128 reads (27%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | chr17:76563547 C>T | 3'Flank (SNP) | VAF 66/283 reads (23%) | called by muse, mutect2, varscan2
- TFR2 | c.966+56G>T | Intron (SNP) | VAF 20/133 reads (15%) | called by muse, mutect2, varscan2
- TOX2 | c.*533A>G | 3'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as rs1004443772; called by muse, mutect2, varscan2
- TRIM36 | c.*171G>A | 3'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- UBB | c.*124A>G | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- VCPIP1 | c.*314C>A | 3'UTR (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100125632; called by muse, mutect2, varscan2
- VGLL3 | c.*8873A>T | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- ZNF502 | c.*1226C>A | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
